Somatic mutation profile of tumor specimen 0DFXH3 from CCDI case PBBSSV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Descended testis; Age at diagnosis: 15.0 years (5,490 days).
Specimen 0DFXH3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72d71898-7791-42af-b3e7-72ecdfe33436.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXF0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ce91128-873a-46e6-905c-38af9b4eb434

The open-access MAF lists 34 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Intron 4, Nonsense Mutation 2, 3'UTR 1, Nonstop Mutation 1, Translation Start Site 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 262/640 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 350/822 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- ABCC3 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 305/1244 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs144530573; called by muse, mutect2, varscan2
- FOXK1 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 407/912 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1461466086, COSV61067516; called by muse, mutect2, varscan2
- GPD1 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 170/696 reads (24%) | catalogued as rs1028373223; called by muse, mutect2, varscan2
- HGF | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 24/552 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV55945295; called by muse, mutect2
- HIVEP1 | c.6974C>T p.T2325I | Missense Mutation (SNP) | VAF 110/755 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.16); catalogued as rs1179491501; called by muse, mutect2, varscan2
- PCNX2 | c.5945G>A p.G1982D | Missense Mutation (SNP) | VAF 144/847 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs1432159163; called by muse, mutect2, varscan2
- FN3KRP | c.386-5G>T | Splice Region (SNP) | VAF 170/337 reads (50%) | called by muse, mutect2, varscan2
- MARCOL | c.857G>T p.*286Lext*? | Nonstop Mutation (SNP) | VAF 89/521 reads (17%) | called by muse, mutect2, varscan2
- MOGAT1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 88/1796 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); called by muse, mutect2
- NUP54 | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 216/562 reads (38%) | called by muse, mutect2, varscan2
- OTUD7A | c.2044_2087del p.D682Hfs*188 (on ENST00000307050 / NM_001382637.1; = p.D675Hfs*188 on NM_130901.3) | Frame Shift Del (DEL) | VAF 43/1146 reads (4%) | called by mutect2, pindel
- PTCHD1 | c.1309C>A p.H437N | Missense Mutation (SNP) | VAF 547/609 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- RANBP2 | c.805G>T p.V269L | Missense Mutation (SNP) | VAF 395/1313 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SF3B1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 208/736 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SF3B3 | c.1523G>A p.C508Y | Missense Mutation (SNP) | VAF 227/806 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- SLC22A13 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 60/1192 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.213); called by muse, mutect2
- SORCS3 | c.3009G>T p.Q1003H | Missense Mutation (SNP) | VAF 32/887 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- STAT4 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 325/1173 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZDHHC1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 241/818 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF335 | c.1637G>A p.S546N | Missense Mutation (SNP) | VAF 78/1598 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2
- DPEP2 | c.378C>T p.L126= | Silent (SNP) | VAF 34/598 reads (6%) | catalogued as rs766803347; called by muse, mutect2
- GIMAP5 | c.871T>C p.L291= | Silent (SNP) | VAF 436/965 reads (45%) | called by muse, mutect2, varscan2
- KRT34 | c.1158C>T p.D386= | Silent (SNP) | VAF 869/2032 reads (43%) | catalogued as rs141543111; called by muse, mutect2, varscan2
- MUC2 | c.921C>A p.G307= | Silent (SNP) | VAF 409/808 reads (51%) | called by muse, mutect2, varscan2
- NCS1 | c.360G>A p.E120= | Silent (SNP) | VAF 354/817 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.96240C>A p.I32080= (on ENST00000591111; = p.I24656= on NM_003319.4) | Silent (SNP) | VAF 358/1720 reads (21%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.1875C>T p.D625= | Silent (SNP) | VAF 41/790 reads (5%) | called by muse, mutect2
- ADH1B | c.*62G>A | 3'UTR (SNP) | VAF 16/440 reads (4%) | catalogued as rs1294973750; called by muse, mutect2
- ERCC1 | c.843+148C>G | Intron (SNP) | VAF 297/570 reads (52%) | called by muse, mutect2, varscan2
- GSDMB | c.576+24C>A | Intron (SNP) | VAF 323/661 reads (49%) | called by muse, mutect2, varscan2
- PSMA1 | c.415-30_415-27del | Intron (DEL) | VAF 152/360 reads (42%) | called by mutect2, pindel, varscan2
- THNSL2 | c.1229+95A>G | Intron (SNP) | VAF 716/2409 reads (30%) | called by muse, mutect2, varscan2
